Somatic mutation profile of tumor specimen 0DITTN from CCDI case PBBTUX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.7 years (3,892 days).
Specimen 0DITTN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfb7be50-e8c7-4d5b-8b43-61773c36da41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DITS9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e21f76fb-acbf-45ec-9798-16ab8bb6e019

The open-access MAF lists 32 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, 5'UTR 2, Intron 2, Frame Shift Del 2, In Frame Ins 1, 3'UTR 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2300_2308dup p.A767_V769dup | In Frame Ins (INS) | VAF 176/584 reads (30%) | hotspot (GDC flag); catalogued as rs727504263; ClinVar: drug response; called by mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 83/658 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 234/511 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781288, CM993216, COSV52664953, COSV52926626, COSV53155598; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.321del p.Y107* | Frame Shift Del (DEL) | VAF 222/583 reads (38%) | hotspot (GDC flag); catalogued as CM154128, COSV52703111, COSV52765697, COSV53067955; called by mutect2, varscan2*
- ARHGEF26 | c.587A>C p.K196T | Missense Mutation (SNP) | VAF 36/362 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV100726486; called by muse, mutect2
- ATRX | c.5263C>G p.L1755V | Missense Mutation (SNP) | VAF 331/741 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100971430, COSV64875446; called by muse, mutect2, varscan2
- DTNA | c.135G>C p.Q45H | Missense Mutation (SNP) | VAF 91/1451 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV51988546; called by muse, mutect2
- MEFV | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 152/304 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs763015849, COSV54819498, COSV99560355; ClinVar: uncertain significance; called by muse, varscan2
- MGA | c.7799C>T p.P2600L (on ENST00000219905 / NM_001164273.1; = p.P2391L on NM_001080541.2) | Missense Mutation (SNP) | VAF 269/692 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780211238, COSV54953395; called by muse, mutect2, varscan2
- TP53 | c.319del p.Y107Tfs*16 | Frame Shift Del (DEL) | VAF 222/577 reads (38%) | catalogued as COSV52679423, COSV53179040; called by mutect2, varscan2*
- TTN | c.47039G>A p.R15680H (on ENST00000591111; = p.R8256H on NM_003319.4) | Missense Mutation (SNP) | VAF 471/1137 reads (41%) | PolyPhen probably damaging (0.998); catalogued as rs530304166; called by muse, mutect2, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 45/1578 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- CDC14C | c.425C>A p.P142Q (on ENST00000428251; = p.P35Q on NM_152627.3) | Missense Mutation (SNP) | VAF 383/1058 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); called by mutect2, varscan2
- HERC6 | c.505C>A p.Q169K | Missense Mutation (SNP) | VAF 46/728 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2
- PADI6 | c.1696A>G p.I566V | Missense Mutation (SNP) | VAF 22/420 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.247); called by muse, mutect2
- PCDHA9 | c.1855A>T p.S619C | Missense Mutation (SNP) | VAF 113/454 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- PRPSAP2 | c.199G>T p.V67L | Missense Mutation (SNP) | VAF 52/1128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- SCN1A | c.2621C>T p.P874L (on ENST00000303395 / NM_001202435.3; = p.P863L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/984 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC18A2 | c.323C>G p.T108S | Missense Mutation (SNP) | VAF 331/1003 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- STS | c.137+1G>T p.X46_splice | Splice Site (SNP) | VAF 46/700 reads (7%) | called by muse, mutect2
- ABCB5 | c.2271C>T p.Y757= (on ENST00000404938 / NM_001163941.2; = p.Y312= on NM_178559.6) | Silent (SNP) | VAF 88/1600 reads (6%) | catalogued as rs370367719; called by muse, mutect2
- C1GALT1C1 | c.591T>A p.L197= | Silent (SNP) | VAF 369/907 reads (41%) | called by muse, mutect2, varscan2
- DOCK3 | c.1299C>T p.F433= | Silent (SNP) | VAF 365/1265 reads (29%) | catalogued as rs139890793; called by muse, varscan2
- DUSP22 | c.66C>T p.D22= | Silent (SNP) | VAF 203/995 reads (20%) | catalogued as rs140760895; called by muse, mutect2, varscan2
- KRT9 | c.120C>T p.G40= | Silent (SNP) | VAF 52/982 reads (5%) | catalogued as rs373248434; called by muse, mutect2
- SH3RF2 | c.1362C>G p.L454= | Silent (SNP) | VAF 54/652 reads (8%) | called by muse, mutect2
- AL441992.2 | c.*4241T>G | 3'UTR (SNP) | VAF 29/81 reads (36%) | called by muse, mutect2
- GAL3ST1 | c.-120+1712A>G | Intron (SNP) | VAF 14/256 reads (5%) | catalogued as rs942911260; called by muse, mutect2
- KPNA7 | c.-30C>T | 5'UTR (SNP) | VAF 43/188 reads (23%) | called by muse, mutect2, varscan2
- RRAGB | chrX:55758388 T>G | 3'Flank (SNP) | VAF 210/417 reads (50%) | called by muse, varscan2
- TMEM35A | c.-75T>C | 5'UTR (SNP) | VAF 13/223 reads (6%) | called by muse, mutect2
- ZP2 | c.484-31A>G | Intron (SNP) | VAF 60/848 reads (7%) | catalogued as rs760330527; called by muse, mutect2
